Somatic mutation profile of tumor specimen TCGA-VQ-A923-01A (aliquot TCGA-VQ-A923-01A-11D-A410-08) from TCGA case TCGA-VQ-A923, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-VQ-A923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 400d3800-fb00-4e4b-bb79-d463f5366c46.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A923-10A (Blood Derived Normal), aliquot TCGA-VQ-A923-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd067e00-1a0d-44bc-be74-16ace6f4ea7f

The open-access MAF lists 110 somatic variants for this specimen: 75 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 34, Nonsense Mutation 9, Splice Site 3, Frame Shift Del 3, In Frame Del 2, RNA 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 42/75 reads (56%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACOX3 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141372938, COSV99067070; called by muse, mutect2, varscan2
- ADGRG4 | c.6300C>A p.Y2100* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99796757; called by muse, mutect2, varscan2
- ARID1A | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 42/96 reads (44%) | catalogued as COSV61376211; called by muse, mutect2, varscan2
- C2orf50 | c.257+1G>T p.X86_splice | Splice Site (SNP) | VAF 5/26 reads (19%) | catalogued as COSV101059474; called by muse, mutect2, varscan2
- CASS4 | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100824770; called by muse, mutect2, varscan2
- CCDC178 | c.1400C>A p.T467N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs760077046, COSV55767541; called by muse, mutect2
- CCND2 | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs781695497, COSV99714474; called by muse, mutect2, varscan2
- CCT8L2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs553618420, COSV63461614; called by muse, mutect2, varscan2
- CEP250 | c.5316_5318del p.L1773del | In Frame Del (DEL) | VAF 12/99 reads (12%) | catalogued as rs769862422; called by pindel, varscan2
- CEP290 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs189280108, COSV100467721; called by muse, mutect2, varscan2
- CNOT1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100410048; called by muse, mutect2, varscan2
- COL12A1 | c.8899T>G p.F2967V | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV100486497; called by muse, mutect2, varscan2
- CREB5 | c.291+2T>A p.X97_splice (on ENST00000357727 / NM_182898.4; = p.X90_splice on NM_004904.3) | Splice Site (SNP) | VAF 20/103 reads (19%) | catalogued as COSV100745498; called by muse, mutect2, varscan2
- CTAGE1 | c.1150C>T p.L384F | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1214543122, COSV101194678; called by muse, mutect2, varscan2
- CUBN | c.5690T>C p.M1897T | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs767014796, COSV100913521; called by muse, mutect2, varscan2
- DLC1 | c.518C>A p.A173E | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV52311014; called by muse, mutect2, varscan2
- EED | c.651A>T p.L217F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99646612; called by muse, mutect2, varscan2
- EPAS1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1254693718, COSV99763644; called by mutect2, varscan2
- EPB41L3 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100550238; called by muse, mutect2, varscan2
- ERCC2 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67263743; called by muse, mutect2
- ESPL1 | c.5999A>G p.Y2000C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229766; called by muse, mutect2, varscan2
- FNDC1 | c.5336C>T p.T1779M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs549929881, COSV51933465; called by muse, mutect2, varscan2
- GALNT2 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100795888; called by muse, mutect2, varscan2
- GSPT2 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100468400; called by muse, mutect2, varscan2
- HSPA13 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99580273; called by muse, mutect2, varscan2
- IDNK | c.411_412del p.E139Gfs*7 | Frame Shift Del (DEL) | VAF 17/79 reads (22%) | catalogued as rs1034341649; called by mutect2, pindel, varscan2
- IFNA4 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 36/164 reads (22%) | catalogued as COSV101427085; called by muse, mutect2, varscan2
- KCNK5 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV100851937; called by muse, mutect2, varscan2
- KDM5C | c.40T>A p.C14S | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100855504; called by muse, mutect2, varscan2
- KIFC3 | c.2355G>C p.Q785H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV101109356; called by muse, mutect2, varscan2
- KLF9 | c.366C>A p.S122R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV101009618; called by muse, mutect2
- KLHL3 | c.1417G>A p.V473M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1212728327, COSV100553561; called by muse, mutect2, varscan2
- KRT78 | c.1114C>T p.Q372* | Nonsense Mutation (SNP) | VAF 21/45 reads (47%) | catalogued as COSV100467622; called by muse, mutect2, varscan2
- LDAH | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV99425925; called by muse, mutect2, varscan2
- LRRC49 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 13/51 reads (25%) | catalogued as rs201403920, COSV99538186; called by muse, mutect2, varscan2
- LYZL2 | c.380C>T p.A127V (on ENST00000375318; = p.A81V on NM_183058.3) | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs150085281; called by muse, mutect2, varscan2
- MBD1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99497230; called by muse, mutect2, varscan2
- MSX1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM013013, COSV66947483; called by muse, mutect2, varscan2
- MUL1 | c.436G>C p.D146H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV99939451; called by muse, mutect2, varscan2
- NCKAP1L | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756906173, COSV53204504, COSV53210746; called by muse, mutect2, varscan2
- NID1 | c.3130C>T p.R1044* | Nonsense Mutation (SNP) | VAF 10/88 reads (11%) | catalogued as COSV99938317; called by muse, mutect2, varscan2
- NPBWR1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV100488304; called by muse, mutect2, varscan2
- OLIG2 | c.262T>G p.S88A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs768519339, COSV60972172; called by muse, mutect2, varscan2
- PCDHA3 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.202); catalogued as COSV65368871; called by muse, mutect2, varscan2
- PGF | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99462759; called by muse, mutect2, varscan2
- PPP1R26 | c.301C>A p.L101I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as COSV100778154; called by muse, mutect2, varscan2
- PPRC1 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV99532086; called by muse, mutect2, varscan2
- PRAMEF1 | c.593C>G p.S198* | Nonsense Mutation (SNP) | VAF 59/410 reads (14%) | catalogued as COSV100180157; called by muse, mutect2, varscan2
- PSG11 | c.803C>A p.P268Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs765772668, COSV60456366; called by muse, mutect2, varscan2
- PTGS1 | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99793544; called by muse, mutect2, varscan2
- RHO | c.295C>A p.L99M | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99960792; called by muse, mutect2
- RSBN1 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1039319392, COSV99793598; called by muse, mutect2
- RYR1 | c.5390G>T p.R1797L | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV100617002, COSV62105705; called by muse, mutect2, varscan2
- SEL1L3 | c.650A>T p.D217V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV99341261; called by muse, mutect2, varscan2
- SH3GL3 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1463995796, COSV61062536; called by muse, mutect2, varscan2
- SHANK1 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs767742502, COSV53252678; called by muse, mutect2, varscan2
- SNX20 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs767585804, COSV56059539; called by muse, mutect2, varscan2
- SPG11 | c.6133A>T p.K2045* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99969629; called by muse, mutect2
- SPIC | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.08); catalogued as COSV100163067; called by muse, mutect2, varscan2
- SPTB | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs143293179; called by muse, mutect2, varscan2
- SPTBN4 | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100152095; called by muse, mutect2
- TLE4 | c.2225C>A p.S742Y | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99513150; called by muse, mutect2, varscan2
- TLX3 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV99740520; called by mutect2, varscan2
- TMEM175 | c.605T>C p.F202S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53280382, COSV99298226; called by muse, mutect2, varscan2
- USP4 | c.1736C>T p.T579M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs747874124, COSV99649753; called by muse, mutect2, varscan2
- WDFY3 | c.9607G>A p.V3203M | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.339); catalogued as rs75223180; called by muse, mutect2, varscan2
- ZDHHC1 | c.1216C>T p.R406W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1289943852, COSV99339573; called by muse, mutect2, varscan2
- ZNF425 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.941); catalogued as COSV100955599; called by muse, mutect2, varscan2
- ZNF792 | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV101289761; called by muse, mutect2, varscan2
- ALDH3A2 | c.1258dup p.S420Ffs*17 | Frame Shift Ins (INS) | VAF 18/116 reads (16%) | called by mutect2, pindel, varscan2
- GRM3 | c.537_546del p.D180Afs*34 | Frame Shift Del (DEL) | VAF 12/126 reads (10%) | called by mutect2, pindel
- PIK3R1 | c.502+4_502+7del p.X168_splice | Splice Site (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel
- PPL | c.3566_3589del p.A1189_V1196del | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, pindel, varscan2
- SLC16A8 | c.1384del p.D462Tfs*32 | Frame Shift Del (DEL) | VAF 14/62 reads (23%) | called by mutect2, pindel, varscan2
- ABCA4 | c.429G>A p.P143= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs138494741; called by muse, mutect2, varscan2
- ADCY9 | c.1671C>T p.S557= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as COSV99570374; called by muse, mutect2, varscan2
- CASQ1 | c.1173C>T p.D391= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1553193083, COSV63623283; called by muse, mutect2
- CILP | c.3276C>T p.L1092= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs144863148; called by muse, mutect2, varscan2
- COL14A1 | c.3387T>C p.G1129= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV99920677; called by muse, mutect2, varscan2
- CPSF1 | c.759C>T p.P253= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs368966053; called by muse, mutect2
- CRP | c.306C>T p.F102= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs369190068, COSV99660752; called by muse, mutect2, varscan2
- CST5 | c.195C>T p.Y65= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as rs1410173707, COSV100489747; called by muse, mutect2, varscan2
- DCST1 | c.615G>A p.T205= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs771996479, COSV55058542, COSV55062260; called by muse, mutect2, varscan2
- DYNC1LI2 | c.147C>G p.S49= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99263262; called by muse, mutect2, varscan2
- EXT2 | c.471C>T p.I157= (on ENST00000343631; = p.I190= on NM_000401.3) | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs747429885, COSV59151541; called by muse, mutect2, varscan2
- FLNC | c.5469G>A p.T1823= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as rs550620019, COSV57959436; ClinVar: likely benign; called by muse, mutect2, varscan2
- FREM2 | c.7752G>A p.L2584= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99750814; called by muse, mutect2, varscan2
- IGHMBP2 | c.1794C>T p.N598= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs1337346956, CM1313521, COSV54819956; called by muse, mutect2, varscan2
- KCNG4 | c.387C>T p.A129= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs1362710513, COSV100377019, COSV57583210; called by muse, mutect2, varscan2
- KCNJ4 | c.1299G>A p.P433= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs777182204, COSV57858183; called by muse, mutect2, varscan2
- LGI2 | c.1008C>T p.D336= | Silent (SNP) | VAF 32/110 reads (29%) | catalogued as rs2232024; called by muse, mutect2, varscan2
- MYBL2 | c.720C>T p.N240= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV99406740; called by muse, mutect2, varscan2
- OR13F1 | c.792T>A p.A264= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV100594853; called by muse, mutect2, varscan2
- PRKCH | c.1056C>T p.I352= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs149356076; called by muse, mutect2, varscan2
- PRKD3 | c.1758G>A p.Q586= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV99306760; called by muse, mutect2, varscan2
- PTPRG | c.1563C>T p.F521= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs1428795599, COSV55655550; called by muse, mutect2
- SFRP4 | c.150G>A p.T50= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as COSV52258837, COSV52260517; called by muse, mutect2, varscan2
- SLC7A13 | c.519C>T p.F173= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV99879030; called by muse, varscan2
- TBX3 | c.429G>A p.L143= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as COSV99984107; called by muse, mutect2, varscan2
- TLX1 | c.933G>A p.P311= | Silent (SNP) | VAF 14/93 reads (15%) | catalogued as rs1241615129, COSV100930014; called by muse, mutect2, varscan2
- TMEM8B | c.987T>A p.A329= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV100941733; called by muse, mutect2, varscan2
- TRIP12 | c.2484G>A p.P828= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as rs371540901; called by muse, mutect2, varscan2
- TTN | c.74322A>T p.G24774= (on ENST00000591111; = p.G17350= on NM_003319.4) | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100629708; called by muse, mutect2, varscan2
- UPF1 | c.3072C>A p.G1024= (on ENST00000599848 / NM_001297549.2; = p.G1013= on NM_002911.4) | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99440400; called by muse, mutect2, varscan2
- UROC1 | c.1239A>G p.R413= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV99332379; called by muse, mutect2, varscan2
- VCAN | c.9888C>T p.C3296= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs758458805, COSV54096535; called by muse, mutect2, varscan2
- VEZF1 | c.375A>T p.R125= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99365927; called by muse, mutect2
- WAS | c.945G>A p.P315= | Silent (SNP) | VAF 16/21 reads (76%) | catalogued as rs781866378, COSV64996897; called by muse, mutect2, varscan2
- SNORD116-29 | n.23dup | RNA (INS) | VAF 8/46 reads (17%) | catalogued as rs749710113; called by mutect2, varscan2
